Gene-level copy-number profile of tumor specimen C3N-01213-01 from CPTAC case C3N-01213, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 68.3 years (24,944 days).
Specimen C3N-01213-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65f40ceb-51fe-4796-8ca0-2a97d9096dfd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01213-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/50b4160d-e68a-4863-89ee-9e6236e82a7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,989; copy number 1: 2,525; copy number 2: 50,428; copy number 3: 219; copy number 4: 2,724; copy number 5: 7; copy number 8: 1; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 2,958 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,999,676–59,000,494, 1 gene: PHBP3.
- chr3:11,745–58,426,127, 1,059 genes (broad region; genes not listed).
- chr8:64,091–7,187,316, 109 genes (broad region; genes not listed).
- chr8:7,298,744–113,616,958, 1,787 genes (broad region; genes not listed).
- chr15:61,729,765–61,731,389, 1 gene: LINC02349.
- chr20:38,977,711–38,978,422, 1 gene (within-gene range 0–2): NPM1P19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,256,904–7,267,536, 2 genes, copy number 16: FAM90A15P, FAM90A3P.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
